Somatic mutation profile of tumor specimen TCGA-41-2573-01A (aliquot TCGA-41-2573-01A-01W-0922-08) from TCGA case TCGA-41-2573, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 60.0 years (21,911 days).
Specimen TCGA-41-2573-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 478d2cb4-bb02-4514-a8ec-b64e0de01aaf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-41-2573-10A (Blood Derived Normal), aliquot TCGA-41-2573-10A-01D-1495-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/06328477-271c-466a-8f9b-ca227b31ce1b

The open-access MAF lists 48 somatic variants for this specimen: 31 protein-altering or splice-affecting, 15 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 15, Frame Shift Ins 4, Nonsense Mutation 2, 3'UTR 1, Splice Site 1, RNA 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTEN | c.284C>T p.P95L | Missense Mutation (SNP) | VAF 101/179 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs786204856, CD132274, CM110120, COSV64288477, COSV64302636; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AKR1B15 | c.427G>A p.G143R | Missense Mutation (SNP) | VAF 34/285 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV71151196; called by muse, mutect2, varscan2
- ALX1 | c.829C>T p.L277F | Missense Mutation (SNP) | VAF 49/164 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.439); catalogued as rs912526043, COSV57491548; called by muse, mutect2, varscan2
- ATP6V0D1 | c.938G>A p.G313D | Missense Mutation (SNP) | VAF 87/235 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.369); catalogued as COSV52097044; called by muse, mutect2, varscan2
- CPNE8 | c.1144-1G>T p.X382_splice | Splice Site (SNP) | VAF 27/119 reads (23%) | catalogued as COSV58839621; called by muse, mutect2, varscan2
- DSP | c.5377G>A p.E1793K | Missense Mutation (SNP) | VAF 27/109 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.846); catalogued as COSV65791726; called by muse, mutect2, varscan2
- GDF5 | c.1040G>A p.R347H | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.233); catalogued as COSV65499987, COSV65501502; called by muse, mutect2, varscan2
- HCLS1 | c.1171G>A p.D391N | Missense Mutation (SNP) | VAF 913/1243 reads (73%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs766873481, COSV57522527; called by muse, mutect2, varscan2
- KCNMB1 | c.527C>T p.A176V | Missense Mutation (SNP) | VAF 68/249 reads (27%) | SIFT tolerated (0.96); PolyPhen benign (0.007); catalogued as COSV51131382, COSV99211278; called by muse, mutect2, varscan2
- KCTD19 | c.2301dup p.V768Rfs*12 | Frame Shift Ins (INS) | VAF 10/90 reads (11%) | catalogued as rs759860142; called by mutect2, varscan2
- LOXL3 | c.824dup p.A277Cfs*57 | Frame Shift Ins (INS) | VAF 22/128 reads (17%) | catalogued as rs746133895; called by mutect2, varscan2
- MDN1 | c.15971C>T p.S5324L | Missense Mutation (SNP) | VAF 144/305 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); catalogued as COSV65518527; called by muse, mutect2, varscan2
- MYH1 | c.1587G>A p.K529= | Splice Region (SNP) | VAF 81/153 reads (53%) | catalogued as rs369732205, COSV56844972; called by muse, mutect2, varscan2
- MYO10 | c.3674dup p.S1226Lfs*25 | Frame Shift Ins (INS) | VAF 26/162 reads (16%) | catalogued as rs760302326, COSV57018963; called by mutect2, varscan2
- OR4C15 | c.788A>T p.N263I (on ENST00000314644; = p.N209I on NM_001001920.2) | Missense Mutation (SNP) | VAF 157/562 reads (28%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0.012); catalogued as COSV58951570; called by muse, mutect2, varscan2
- PLA2G4A | c.294G>A p.M98I | Missense Mutation (SNP) | VAF 116/214 reads (54%) | SIFT tolerated (0.52); PolyPhen benign (0.034); catalogued as COSV66552435; called by muse, mutect2, varscan2
- PRSS1 | c.253G>A p.E85K | Missense Mutation (SNP) | VAF 411/1064 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs759654213, COSV100298050, COSV61191308, COSV61195806; called by muse, mutect2, varscan2
- RYR2 | c.1646C>G p.A549G | Missense Mutation (SNP) | VAF 22/113 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as CM097928, COSV100772061, COSV63670037; called by muse, mutect2, varscan2
- SLC17A6 | c.1694T>C p.V565A | Missense Mutation (SNP) | VAF 36/70 reads (51%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV54134331, COSV54141814; called by muse, mutect2, varscan2
- SLC44A5 | c.411A>T p.K137N | Missense Mutation (SNP) | VAF 50/225 reads (22%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV63759683; called by muse, mutect2, varscan2
- SOHLH1 | c.938C>T p.S313L | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs538962017, COSV53680882; called by muse, mutect2
- SSC4D | c.85C>T p.P29S | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.052); catalogued as rs748947448, COSV51881655, COSV51882963; called by muse, mutect2
- TFE3 | c.1445dup p.P483Tfs*138 | Frame Shift Ins (INS) | VAF 28/188 reads (15%) | catalogued as rs782753958; called by mutect2, varscan2
- TMEM200A | c.661C>T p.R221* | Nonsense Mutation (SNP) | VAF 22/79 reads (28%) | catalogued as rs267600806; called by muse, mutect2, varscan2
- UGT2A3 | c.1411G>T p.A471S | Missense Mutation (SNP) | VAF 104/212 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV52359178; called by muse, mutect2, varscan2
- USP6 | c.1399T>A p.W467R | Missense Mutation (SNP) | VAF 13/17 reads (76%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.608); catalogued as COSV51477008; called by muse, mutect2, varscan2
- YARS2 | c.224C>G p.T75S | Missense Mutation (SNP) | VAF 118/190 reads (62%) | SIFT tolerated (0.41); PolyPhen benign (0.04); catalogued as rs866901757, COSV61401472; called by muse, mutect2, varscan2
- ZNF10 | c.1051T>C p.C351R | Missense Mutation (SNP) | VAF 66/220 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50211714; called by muse, mutect2, varscan2
- AREL1 | c.166G>A p.D56N | Missense Mutation (SNP) | VAF 10/216 reads (5%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.978); called by muse, mutect2
- BIRC6 | c.10489G>T p.V3497L | Missense Mutation (SNP) | VAF 16/512 reads (3%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.55); called by muse, mutect2
- HP1BP3 | c.448C>T p.Q150* | Nonsense Mutation (SNP) | VAF 10/159 reads (6%) | called by muse, mutect2
- ADGRF4 | c.1428G>A p.V476= | Silent (SNP) | VAF 21/567 reads (4%) | catalogued as COSV51954795; called by muse, mutect2
- COL5A1 | c.363C>T p.N121= | Silent (SNP) | VAF 33/61 reads (54%) | catalogued as rs369180922; ClinVar: likely benign; called by muse, mutect2, varscan2
- FA2H | c.966G>A p.S322= | Silent (SNP) | VAF 27/164 reads (16%) | catalogued as rs766614299, COSV54725567; called by muse, mutect2, varscan2
- IMPDH2 | c.663C>T p.I221= | Silent (SNP) | VAF 116/148 reads (78%) | catalogued as COSV100454930, COSV58707440; called by muse, mutect2, varscan2
- MAP3K1 | c.3708G>A p.P1236= | Silent (SNP) | VAF 63/181 reads (35%) | catalogued as rs774493506, COSV68122405; called by muse, mutect2, varscan2
- MAS1L | c.633C>T p.F211= | Silent (SNP) | VAF 58/111 reads (52%) | catalogued as COSV65808620; called by muse, mutect2, varscan2
- MAST1 | c.1407G>A p.L469= | Silent (SNP) | VAF 5/34 reads (15%) | called by muse, mutect2, varscan2
- MTG1 | c.357C>A p.V119= | Silent (SNP) | VAF 3/48 reads (6%) | called by muse, mutect2
- OR51D1 | c.891T>A p.P297= | Silent (SNP) | VAF 368/873 reads (42%) | catalogued as COSV62913982; called by muse, mutect2, varscan2
- POLB | c.633A>G p.L211= | Silent (SNP) | VAF 23/65 reads (35%) | catalogued as rs750255941, COSV55345541; called by muse, mutect2, varscan2
- PPM1D | c.945A>T p.G315= | Silent (SNP) | VAF 122/218 reads (56%) | catalogued as COSV59954718; called by muse, mutect2, varscan2
- RXFP4 | c.483C>T p.A161= | Silent (SNP) | VAF 372/422 reads (88%) | called by mutect2, varscan2
- TNFAIP1 | c.486C>T p.Y162= | Silent (SNP) | VAF 10/123 reads (8%) | catalogued as rs371221886; called by muse, mutect2
- TONSL | c.2616C>T p.P872= | Silent (SNP) | VAF 9/25 reads (36%) | catalogued as COSV68047857; called by muse, mutect2, varscan2
- VWF | c.2943C>T p.S981= | Silent (SNP) | VAF 289/666 reads (43%) | catalogued as rs369031938; called by muse, mutect2, varscan2
- LEKR1 | c.*1449C>T | 3'UTR (SNP) | VAF 134/201 reads (67%) | catalogued as rs1397592829, COSV62960949; called by muse, mutect2, varscan2
- SNORD115-16 | n.72C>T | RNA (SNP) | VAF 26/66 reads (39%) | catalogued as rs764133027; called by muse, mutect2, varscan2
